Somatic mutation profile of tumor specimen MP2PRT-PAVSLS-TMP1-A (aliquot MP2PRT-PAVSLS-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVSLS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,957 days).
Specimen MP2PRT-PAVSLS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73e3b795-7088-4f17-aa95-67fd93609977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSLS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSLS-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d42b1a9a-9cfd-43e4-9232-eacd746721e8

The open-access MAF lists 12 somatic variants for this specimen: 4 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 4, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL1 | c.3340G>A p.A1114T | Missense Mutation (SNP) | VAF 195/443 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs759006157; called by muse, mutect2, varscan2
- MUC16 | c.20008G>A p.V6670I | Missense Mutation (SNP) | VAF 95/410 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as rs745640624, COSV67463250; called by muse, mutect2, varscan2
- PKHD1L1 | c.6916G>A p.A2306T | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1182649257; called by muse, mutect2, varscan2
- ZBED5 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DZIP1 | c.108C>T p.A36= | Silent (SNP) | VAF 104/670 reads (16%) | called by mutect2, varscan2
- GRM1 | c.792C>T p.N264= | Silent (SNP) | VAF 169/394 reads (43%) | catalogued as rs1169222222, COSV51111790; called by muse, mutect2, varscan2
- RADX | c.1896C>T p.H632= | Silent (SNP) | VAF 183/310 reads (59%) | catalogued as rs766456103, COSV65318409; called by muse, mutect2, varscan2
- TECTA | c.4245C>T p.N1415= | Silent (SNP) | VAF 240/512 reads (47%) | catalogued as COSV50687776; called by muse, mutect2, varscan2
- TTC9B | c.273G>A p.A91= | Silent (SNP) | VAF 235/888 reads (26%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.207G>A p.P69= | Silent (SNP) | VAF 185/438 reads (42%) | catalogued as rs753390128, COSV59168795; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2985A>G | Intron (SNP) | VAF 96/401 reads (24%) | called by muse, mutect2, varscan2
- TJP1 | c.*1289dup | 3'UTR (INS) | VAF 20/117 reads (17%) | catalogued as rs905619523; called by mutect2, varscan2
